Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABM9, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABM9-TTP1-A (Primary Tumor).

CDDP-YP-ABM9-01-PR

Material description

Fragment of VI right rib + limph nodes station 9-4-10-7 + right bilobectomy

- A) A lymph node, station 9
- B) A lymph node, station 4
- C) 3 lymph nodes, station 10
- D) 11 lymph nodes, station 7
- E) Fragment of N right rib
- F) Margin of bronchial resection
- G) Neoplasm of lower lobe, right lung + visceral pleura
- H) Neoplasm - visceral pleura
- I) 9 peribronchial lymph nodes
- J) Parenchyma of lower lobe, right lung
- K) Parenchyma of middle lobe

ICD - 0 - 3

Adenocarcinoma, NOS 8140/3
Site: (R) lung, lower lobe C34.2

ICD-10

C34.11

hw
12/40/16

Diagnosis

- A) Nodular carcinomatous metastasis
- B-E) No signs of neoplasm
- F) Deep microfocus of neoplastic infiltration of the margin of resection
- G-H) Moderately differentiated adenocarcinoma with zonal squamous areas infiltrating up to the visceral pleura (sample of pulmonary bilobectomy with peripheral neoplasm from the apical segment of lower lobe of maximum diameter of 3 cm placed macroscopically at 2,9 cm of the bronchial resection margin)
- I) Massive metastases in 8 lymph nodes
- J-K) Pulmonary parenchyma with framework of atelectasis.

Staging pTNM:

pT3, pN2, G2

Source: NCI Genomic Data Commons file 5c876399-8ba8-4a1b-9138-b30d6e04bbcd (CDDP-ABM9-TTP1.BFC9C5D6-B108-4752-AFCE-AB08A11E4A8F.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).